Gene-level copy-number profile of tumor specimen ALCH-B2V3-TTP1-A from ALCHEMIST case ALCH-B2V3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.9 years (27,002 days).
Specimen ALCH-B2V3-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00f21cb3-cbfe-42b7-9748-bfdccdeb05d2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2V3-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/b2849ea2-4cfc-4059-84ca-4a0c75ea6371

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 7,896; copy number 2: 46,680; copy number 3: 3,262; copy number 4: 233; copy number 5: 294.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,523,857, 4 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2.
- chr4:119,434,005–119,434,108, 1 gene: RNU6-1217P.
- chr6:29,887,294–29,888,268, 1 gene (within-gene range 0–1): AL645929.1.
- chr6:29,896,654–29,934,286, 6 genes: HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr6:157,981,863–158,099,176, 3 genes (within-gene range 0–1): SYNJ2, AL139330.1, SYNJ2-IT1.
- chr9:21,802,636–22,214,672, 15 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr17:18,450,244–18,475,920, 4 genes (within-gene range 0–1): KRT16P4, AL353997.1, AL353997.4, TNPO1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 294 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,996,086–153,923,360, 169 genes, copy number 5 (broad region; genes not listed).
- chr1:154,502,219–156,661,424, 119 genes, copy number 5 (broad region; genes not listed).
- chr1:193,473,224–194,198,708, 4 genes, copy number 5 (within-gene range 2–5): AL136456.1, AL357793.1, AL357793.2, RPL23AP22.
- chr6:32,517,353–32,530,287, 1 gene, copy number 5: HLA-DRB5.
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 7,896. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
